Somatic mutation profile of tumor specimen TARGET-30-PARZKK-09A (aliquot TARGET-30-PARZKK-09A-01D) from TARGET case TARGET-30-PARZKK, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.1 years (412 days).
Specimen TARGET-30-PARZKK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b39096b-eed9-4c30-a608-ab067f367cc3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARZKK-10A (Blood Derived Normal), aliquot TARGET-30-PARZKK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cd75570-a507-446a-8686-72c1f81a8e73

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMB2 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs773027067, COSV59731224; called by muse, mutect2, varscan2
